Somatic mutation profile of tumor specimen C3N-01074-01 (aliquot CPT0105270009) from CPTAC case C3N-01074, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 57.0 years (20,803 days).
Specimen C3N-01074-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4d91e72-19c3-44fd-b3f8-49810a67922b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01074-31 (Blood Derived Normal), aliquot CPT0107740002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beac2715-e443-41c5-bb85-6c53f9573bb5

The open-access MAF lists 609 somatic variants for this specimen: 415 protein-altering or splice-affecting, 113 silent, 81 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 345, Silent 113, Intron 40, Nonsense Mutation 24, RNA 17, Splice Site 16, Frame Shift Del 15, 3'UTR 12, Splice Region 9, 3'Flank 8, Frame Shift Ins 4, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 593/933 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NR2F2 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as rs1555446980, COSV67683347; ClinVar: pathogenic; called by muse, mutect2
- ORAI1 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 73/514 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555322610; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 54/131 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981868, COSV58822591, COSV58830751; called by muse, mutect2, varscan2
- TP53 | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 195/430 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 102/621 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as rs1257928056; called by muse, mutect2, varscan2
- ABCA2 | c.3308A>G p.H1103R (on ENST00000614293; = p.H1073R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/361 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1292669939; called by muse, mutect2, varscan2
- ABCD2 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 33/244 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV58049600; called by muse, mutect2, varscan2
- ABCE1 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56847888; called by muse, mutect2, varscan2
- ACTC1 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.428); catalogued as COSV51761187; called by muse, mutect2, varscan2
- ACTG1 | c.975del p.M325Ifs*65 | Frame Shift Del (DEL) | VAF 46/502 reads (9%) | catalogued as COSV100111954; called by mutect2, pindel
- ADAMTS8 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 93/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776551880, COSV57291160; called by muse, mutect2, varscan2
- ALK | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1023566110; called by muse, mutect2, varscan2
- ANGPT4 | c.338G>T p.R113M | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV67922069, COSV67922571; called by muse, mutect2, varscan2
- ANKRD34C | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs118125046; called by muse, mutect2, varscan2
- ATP10B | c.3237G>T p.Q1079H | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100515642; called by muse, mutect2, varscan2
- ATP8B4 | c.1492del p.A498Lfs*2 | Frame Shift Del (DEL) | VAF 46/219 reads (21%) | catalogued as COSV99034108; called by mutect2, pindel, varscan2
- BRINP2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 33/166 reads (20%) | catalogued as COSV64180980; called by muse, mutect2, varscan2
- BTBD17 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64729257; called by muse, mutect2, varscan2
- C11orf42 | c.770C>G p.A257G | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.055); catalogued as COSV56412529; called by muse, mutect2, varscan2
- C18orf25 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 140/487 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56366189; called by muse, mutect2, varscan2
- CADM3 | c.940C>G p.L314V (on ENST00000368125 / NM_001127173.3; = p.L348V on NM_021189.5) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63685514; called by muse, mutect2
- CLIP2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554732690; called by muse, mutect2, varscan2
- CTAGE1 | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 213/748 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66944050; called by muse, mutect2, varscan2
- DEDD | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV100919098; called by muse, mutect2, varscan2
- DNAH7 | c.5441G>T p.R1814L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV100413838, COSV56751102; called by muse, mutect2, varscan2
- FAM71B | c.421C>A p.R141S | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57227377; called by muse, mutect2, varscan2
- FCRL3 | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as rs567003130; called by muse, mutect2, varscan2
- FLG | c.5350C>A p.P1784T | Missense Mutation (SNP) | VAF 60/589 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as rs753760290, COSV64238506; called by muse, mutect2
- FOXG1 | c.654C>G p.Y218* | Nonsense Mutation (SNP) | VAF 84/1204 reads (7%) | catalogued as COSV100486507; called by muse, mutect2
- FPR2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763580618, COSV60672258, COSV60672939, COSV60674829; called by muse, mutect2, varscan2
- FSCB | c.1673A>T p.E558V | Missense Mutation (SNP) | VAF 60/387 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); catalogued as COSV61216987; called by muse, mutect2, varscan2
- GLI3 | c.3893C>A p.P1298Q | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.238); catalogued as rs182571462; called by muse, mutect2, varscan2
- GNRHR | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as CM119294; called by muse, mutect2, varscan2
- GON4L | c.3909G>T p.E1303D | Missense Mutation (SNP) | VAF 49/995 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs144659040; called by muse, mutect2
- GPM6A | c.322G>T p.G108W | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54534164, COSV99704812; called by muse, mutect2, varscan2
- GPR152 | c.93G>T p.W31C | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56886334; called by muse, mutect2, varscan2
- GPR158 | c.1079A>T p.H360L | Missense Mutation (SNP) | VAF 82/328 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as rs149833592; called by muse, mutect2, varscan2
- GREB1L | c.653A>T p.Y218F | Missense Mutation (SNP) | VAF 94/382 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52549192; called by muse, mutect2, varscan2
- HCFC2 | c.1232-2A>T p.X411_splice | Splice Site (SNP) | VAF 68/240 reads (28%) | catalogued as COSV99982803; called by muse, mutect2, varscan2
- HOXD10 | c.138T>A p.Y46* | Nonsense Mutation (SNP) | VAF 30/218 reads (14%) | catalogued as COSV50898210; called by muse, mutect2, varscan2
- HPN | c.583G>T p.G195W | Missense Mutation (SNP) | VAF 75/279 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV52883475, COSV52886513; called by muse, mutect2, varscan2
- HSPA12A | c.1919G>T p.R640M | Missense Mutation (SNP) | VAF 128/428 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65022988; called by muse, mutect2, varscan2
- HSPB3 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 72/421 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.591); catalogued as COSV100116041; called by muse, mutect2, varscan2
- IGKV3-20 | c.150C>A p.S50R | Missense Mutation (SNP) | VAF 199/644 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs11546074; called by muse, mutect2, varscan2
- IKBKB | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as rs200136227; called by muse, mutect2, varscan2
- INA | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100878610; called by muse, mutect2, varscan2
- KCNT1 | c.1168C>G p.P390A (on ENST00000488444; = p.P409A on NM_020822.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as CM159169; called by muse, mutect2, varscan2
- KIF1A | c.2471C>A p.S824Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57504520; called by muse, mutect2, varscan2
- KRT34 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 199/594 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs781546162, COSV67450661; called by muse, mutect2, varscan2
- KRT6B | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 202/581 reads (35%) | catalogued as rs757008227; called by muse, mutect2, varscan2
- LAMP5 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99855504; called by muse, mutect2, varscan2
- LARP6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100150751; called by muse, mutect2, varscan2
- LELP1 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 113/373 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV64202603; called by muse, mutect2, varscan2
- LRFN2 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV57824115; called by muse, mutect2, varscan2
- LRIT1 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV64512629; called by muse, mutect2, varscan2
- MAEL | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100901665; called by muse, mutect2, varscan2
- MAGI2 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 59/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62681604; called by muse, mutect2, varscan2
- MAMDC2 | c.1045T>C p.C349R | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1281123532; called by muse, mutect2, varscan2
- MC2R | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs202040791, COSV100562975; called by muse, mutect2, varscan2
- MCC | c.289del p.R97Afs*13 | Frame Shift Del (DEL) | VAF 55/353 reads (16%) | catalogued as COSV68726916; called by mutect2, pindel, varscan2
- MFAP5 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 129/275 reads (47%) | catalogued as CM1412093, COSV63945507; called by muse, mutect2, varscan2
- MFHAS1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52284096; called by muse, mutect2, varscan2
- MYH13 | c.644A>C p.Q215P | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99355350; called by muse, mutect2, varscan2
- NCOR2 | c.6886C>T p.R2296W | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs370685396; called by muse, mutect2, varscan2
- NDST1 | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 87/428 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.951); catalogued as rs773934403, COSV55788456; called by muse, mutect2, varscan2
- NF1 | c.3869A>T p.K1290M | Missense Mutation (SNP) | VAF 148/483 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CD1415164; called by muse, mutect2, varscan2
- NLGN4X | c.2284C>G p.L762V | Missense Mutation (SNP) | VAF 105/219 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as rs764361221; called by muse, mutect2, varscan2
- NLRP2 | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 102/407 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54757301; called by muse, mutect2, varscan2
- NLRP7 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as COSV60173165; called by muse, mutect2
- NMBR | c.1076C>G p.A359G | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as COSV57800651; called by muse, mutect2, varscan2
- NOS2 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs746482593; called by muse, mutect2, varscan2
- NOTCH1 | c.1558T>A p.F520I | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99077672; called by muse, mutect2, varscan2
- NTN5 | c.1048A>T p.N350Y | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV54307625; called by muse, mutect2, varscan2
- NTRK3 | c.1885C>T p.L629F | Missense Mutation (SNP) | VAF 133/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62312072; called by muse, mutect2, varscan2
- OR10G4 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100304744, COSV100304816; called by muse, mutect2
- OR1S1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.804); catalogued as COSV58707341; called by muse, mutect2, varscan2
- OR2T8 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV60662651; called by muse, varscan2
- OR5M1 | c.162C>A p.H54Q | Missense Mutation (SNP) | VAF 61/493 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs536324080, COSV101591572, COSV73201996; called by muse, mutect2, varscan2
- OR5M11 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 44/253 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.242); catalogued as COSV101602068; called by muse, mutect2, varscan2
- OR7G2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 134/333 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201831795, COSV59687968; called by muse, mutect2, varscan2
- PALD1 | c.1519C>T p.R507W | Missense Mutation (SNP) | VAF 101/403 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771483890; called by muse, mutect2, varscan2
- PANX3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV52511648; called by muse, mutect2, varscan2
- PASK | c.2826G>T p.R942S | Missense Mutation (SNP) | VAF 64/355 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV99300510; called by muse, mutect2, varscan2
- PCDHB10 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.41); catalogued as COSV53381783; called by muse, mutect2, varscan2
- PCDHGB1 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as rs764756339; called by muse, mutect2, varscan2
- PITX2 | c.600G>T p.M200I (on ENST00000354925 / NM_001204397.1; = p.M207I on NM_000325.6) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV60741103; called by muse, mutect2, varscan2
- PIWIL4 | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV54409048; called by muse, mutect2, varscan2
- PLA2R1 | c.2247G>T p.W749C | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322678; called by muse, mutect2, varscan2
- PLAU | c.349G>T p.G117W | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101032187; called by muse, mutect2, varscan2
- PPP4R1 | c.2547+1G>T p.X849_splice (on ENST00000400556 / NM_001042388.3; = p.X832_splice on NM_005134.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 76/242 reads (31%) | catalogued as COSV53280433; called by muse, mutect2, varscan2
- PRKD1 | c.2167-1G>T p.X723_splice | Splice Site (SNP) | VAF 32/189 reads (17%) | catalogued as COSV59577682; called by muse, mutect2, varscan2
- RASAL1 | c.615G>T p.M205I | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs1481356112; called by muse, mutect2, varscan2
- RELN | c.10287C>T p.S3429= | Splice Region (SNP) | VAF 187/678 reads (28%) | catalogued as COSV59043947; called by muse, mutect2, varscan2
- RHPN1 | c.150G>T p.M50I | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs773014512; called by muse, mutect2, varscan2
- RIMS2 | c.2257G>C p.D753H (on ENST00000666250 / NM_001348490.2; = p.D561H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51723589; called by muse, varscan2
- RSAD1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375677855; called by muse, mutect2, varscan2
- SALL4 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 84/419 reads (20%) | catalogued as COSV53852164; called by muse, mutect2, varscan2
- SDHA | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 171/468 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as CM1510431, COSV53772490; called by muse, mutect2, varscan2
- SERPINA12 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 97/267 reads (36%) | catalogued as rs557748313; called by muse, mutect2, varscan2
- SI | c.2700C>A p.N900K | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100013261, COSV52269713; called by muse, mutect2, varscan2
- SLC22A9 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.029); catalogued as rs758419513; called by muse, mutect2, varscan2
- SLIT1 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 64/237 reads (27%) | catalogued as COSV56595744; called by muse, mutect2, varscan2
- SMO | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs142599757, COSV50825607; called by muse, mutect2, varscan2
- SPATA31A6 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 92/561 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60534911; called by mutect2, varscan2
- SPTA1 | c.7055A>C p.K2352T | Missense Mutation (SNP) | VAF 22/580 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV63749787; called by muse, mutect2
- SRD5A1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1295072307; called by muse, mutect2
- STRN | c.558G>T p.L186F | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1043050578; called by muse, mutect2, varscan2
- TACR3 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV100510104; called by muse, mutect2, varscan2
- TBX18 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV63736547; called by muse, mutect2, varscan2
- TG | c.5042G>T p.G1681V | Missense Mutation (SNP) | VAF 214/647 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV99604066; called by muse, mutect2, varscan2
- TMEM225 | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66694201; called by muse, mutect2, varscan2
- TRDN | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.081); catalogued as COSV62113095; called by muse, mutect2, varscan2
- TRO | c.2711G>T p.S904I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV51503048; called by muse, mutect2, varscan2
- TTC39B | c.2028G>T p.W676C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV52618175; called by muse, mutect2, varscan2
- TXN2 | c.168G>T p.R56S | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs61730813; called by muse, mutect2, varscan2
- USP7 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 49/371 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.498); catalogued as COSV61216595; called by muse, varscan2
- WASH6P | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 85/619 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as rs772507094; called by muse, mutect2, varscan2
- ZCCHC8 | c.886C>G p.Q296E | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs775988353; called by muse, varscan2
- ZFHX4 | c.8414C>A p.S2805* | Nonsense Mutation (SNP) | VAF 71/295 reads (24%) | catalogued as COSV50501474; called by muse, mutect2, varscan2
- ZNF208 | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs781415667; called by muse, mutect2, varscan2
- ZNF208 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68100587; called by muse, mutect2, varscan2
- ZNF234 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70602961; called by muse, mutect2, varscan2
- ZNF525 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 95/313 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs750291577; called by muse, mutect2, varscan2
- ZNF835 | c.863del p.A288Gfs*6 | Frame Shift Del (DEL) | VAF 84/396 reads (21%) | catalogued as COSV73379186; called by mutect2, pindel, varscan2
- ZRANB2 | c.987G>C p.K329N | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV54671139; called by muse, mutect2, varscan2
- ABL1 | c.841del p.E281Kfs*4 | Frame Shift Del (DEL) | VAF 37/159 reads (23%) | called by pindel, varscan2
- ACSM4 | c.1490T>A p.V497D | Missense Mutation (SNP) | VAF 409/750 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM6 | c.562G>C p.V188L | Missense Mutation (SNP) | VAF 174/605 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- ACTN2 | c.784G>T p.A262S | Missense Mutation (SNP) | VAF 63/387 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAM32 | c.2199C>A p.S733R | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ADAM7 | c.1538G>T p.G513V | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2804A>G p.H935R | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRV1 | c.13894-2A>T p.X4632_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- ADNP2 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- AHNAK | c.4123G>A p.G1375S | Missense Mutation (SNP) | VAF 143/444 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AJAP1 | c.175del p.R59Gfs*94 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | called by pindel, varscan2
- AK5 | c.719T>A p.V240E (on ENST00000354567 / NM_174858.3; = p.V214E on NM_012093.4) | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AKAP6 | c.2838G>T p.E946D | Missense Mutation (SNP) | VAF 342/569 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALPK2 | c.2729A>T p.N910I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ALX4 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ANKRD33 | c.482G>T p.R161L (on ENST00000340970 / NM_001304459.2; = p.R286L on NM_182608.4) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- APBA2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 100/686 reads (15%) | called by mutect2, varscan2
- ARFGEF3 | c.5932A>C p.S1978R | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ASCC3 | c.5181A>T p.L1727F | Missense Mutation (SNP) | VAF 48/308 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAHCC1 | c.1886A>G p.E629G | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- BOC | c.2669T>A p.L890Q | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- BRSK2 | c.904G>A p.V302M | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C11orf16 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 58/319 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- C1orf127 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- C4orf54 | c.1442C>A p.P481Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C7 | c.1583C>A p.P528H | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C8orf76 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 459/1763 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA11 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 68/267 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CACNA1B | c.5569G>T p.A1857S | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CACNB2 | c.694T>A p.L232I (on ENST00000324631 / NM_201596.3; = p.L177I on NM_000724.4) | Missense Mutation (SNP) | VAF 175/575 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CARMIL2 | c.988A>T p.T330S | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP12 | c.367G>T p.G123W | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASS4 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 77/221 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CCDC102B | c.342del p.N114Kfs*12 | Frame Shift Del (DEL) | VAF 124/535 reads (23%) | called by mutect2, pindel, varscan2
- CCDC166 | c.815T>A p.L272Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC68 | c.658A>C p.K220Q | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CCDC74B | c.339G>C p.L113F | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CCDC85A | c.1378G>T p.G460W | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CCER1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CD1C | c.730C>A p.Q244K | Missense Mutation (SNP) | VAF 15/433 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.271); called by muse, mutect2
- CDC14C | c.433G>A p.A145T (on ENST00000428251; = p.A38T on NM_152627.3) | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDR2L | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CEP290 | c.5017C>A p.Q1673K | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.228); called by muse, mutect2
- CFAP46 | c.7982C>A p.A2661D | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CFAP52 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC9A | c.222A>T p.Q74H | Missense Mutation (SNP) | VAF 62/692 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- CNTNAP2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 68/505 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- COL20A1 | c.3239C>A p.P1080Q | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL27A1 | c.1999_2000insT p.G667Vfs*26 | Frame Shift Ins (INS) | VAF 27/201 reads (13%) | called by mutect2, pindel, varscan2
- CPED1 | c.1407+1G>C p.X469_splice | Splice Site (SNP) | VAF 40/153 reads (26%) | called by muse, mutect2, varscan2
- CPN2 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 101/237 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACD | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CRB1 | c.920C>A p.S307* | Nonsense Mutation (SNP) | VAF 66/433 reads (15%) | called by muse, mutect2, varscan2
- CRYBB1 | c.180G>C p.R60S | Missense Mutation (SNP) | VAF 69/364 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CSMD1 | c.8416G>T p.A2806S (on ENST00000520002; = p.A2805S on NM_033225.6) | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CT47B1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- CTBS | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CTNND2 | c.57C>A p.D19E | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CUX2 | c.4343G>T p.S1448I | Missense Mutation (SNP) | VAF 105/365 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDR2 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 18/554 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DENND4B | c.2956G>T p.G986W | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLGAP3 | c.2660C>A p.T887N | Missense Mutation (SNP) | VAF 212/456 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMBX1 | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- DNAI4 | c.1516G>T p.G506W | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK2 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- DOCK5 | c.2950G>C p.D984H | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DXO | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 111/415 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EGFR | c.3162G>T p.G1054= | Splice Region (SNP) | VAF 128/391 reads (33%) | called by muse, mutect2, varscan2
- ELFN1 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- ENTR1 | c.617C>A p.S206* (on ENST00000357365 / NM_001039707.2; = p.S183* on NM_006643.4) | Nonsense Mutation (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- EPCAM | c.379A>T p.T127S | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- EYA4 | c.278-6A>T | Splice Region (SNP) | VAF 50/325 reads (15%) | called by muse, mutect2, varscan2
- EYS | c.5009C>A p.P1670H | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EYS | c.4534G>T p.A1512S | Missense Mutation (SNP) | VAF 115/486 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAF2 | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM186A | c.1752C>G p.S584R | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FAM227A | c.1325A>C p.Q442P | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM71F2 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- FAM95C | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- FGD5 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FGF12 | c.703G>T p.G235C (on ENST00000454309 / NM_021032.5; = p.G173C on NM_004113.6) | Missense Mutation (SNP) | VAF 95/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FLG2 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 104/615 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- FPR1 | c.935T>A p.L312Q | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FRMD6 | c.1551G>C p.K517N (on ENST00000344768 / NM_001267046.2; = p.K509N on NM_152330.4) | Missense Mutation (SNP) | VAF 85/765 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FYB1 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 88/249 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABBR2 | c.1343C>T p.T448I | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRB3 | c.522C>A p.N174K | Missense Mutation (SNP) | VAF 90/560 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by mutect2, varscan2
- GAL3ST3 | c.929C>A p.A310E | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.98); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GALNT14 | c.1001T>A p.V334D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAREM2 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GIMAP5 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GLDN | c.464A>T p.H155L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- GNB1 | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- GOLGA6L9 | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 96/1236 reads (8%) | called by muse, varscan2
- GPR50 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GPR89B | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- GRM8 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- HAS1 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HASPIN | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- HAX1 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 31/745 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HBD | c.138dup p.G47Wfs*7 | Frame Shift Ins (INS) | VAF 62/453 reads (14%) | called by mutect2, varscan2
- HIP1R | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 182/630 reads (29%) | called by muse, mutect2, varscan2
- HPSE | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- HS3ST2 | c.215C>G p.P72R | Missense Mutation (SNP) | VAF 66/355 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HSPA6 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 100/329 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ICE1 | c.1841A>T p.D614V | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IGDCC3 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 30/154 reads (19%) | called by muse, mutect2
- IGKV1D-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 146/834 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- IL7R | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- IL7R | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 69/462 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- INSRR | c.843del p.S282Afs*49 | Frame Shift Del (DEL) | VAF 22/125 reads (18%) | called by mutect2, pindel, varscan2
- INSYN1 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- INTS6L | c.1936G>T p.G646* | Nonsense Mutation (SNP) | VAF 42/248 reads (17%) | called by muse, mutect2, varscan2
- ITGA11 | c.510T>A p.D170E | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCMF1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); called by muse, varscan2
- KCNG1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KCNG4 | c.1212C>A p.S404R | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5A | c.2641G>T p.G881C | Missense Mutation (SNP) | VAF 284/487 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- KHDRBS3 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KIF26B | c.1899dup p.I634Hfs*39 | Frame Shift Ins (INS) | VAF 10/44 reads (23%) | called by pindel, varscan2
- KIRREL3 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- KLK5 | c.815C>A p.P272Q | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KPRP | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- KRT36 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT71 | c.1209G>C p.Q403H | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LAMA4 | c.201C>A p.C67* | Nonsense Mutation (SNP) | VAF 73/484 reads (15%) | called by muse, mutect2, varscan2
- LIMS2 | c.359G>C p.R120T (on ENST00000355119 / NM_001161403.3; = p.R144T on NM_017980.4) | Missense Mutation (SNP) | VAF 85/212 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- LIPF | c.-11G>T | Splice Region (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- LMBRD2 | c.849G>T p.M283I | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- LNX1 | c.1274A>T p.E425V (on ENST00000263925 / NM_001126328.3; = p.E329V on NM_032622.2) | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LOXHD1 | c.1881A>T p.K627N | Missense Mutation (SNP) | VAF 96/373 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LRIG1 | c.2965C>G p.P989A | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.7988G>T p.G2663V | Missense Mutation (SNP) | VAF 13/312 reads (4%) | called by muse, mutect2
- MAN2A1 | c.1377A>T p.I459= | Splice Region (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- MAPK7 | c.1898G>C p.C633S | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, varscan2
- MARK2 | c.289-7C>G | Splice Region (SNP) | VAF 69/172 reads (40%) | called by muse, mutect2, varscan2
- METTL18 | c.22_23del p.T8Yfs*8 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- MEX3D | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 81/206 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL3 | c.4171C>A p.L1391M | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MOCOS | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2A | c.1835C>A p.P612H | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- MRPS9 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MS4A14 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC12 | c.1028C>G p.P343R (on ENST00000379442; = p.P200R on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MUC16 | c.23260C>A p.L7754M | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MYBBP1A | c.30_31del p.M10Ifs*36 | Frame Shift Del (DEL) | VAF 25/234 reads (11%) | called by mutect2, pindel, varscan2
- MYOCD | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 146/374 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- NAV3 | c.2914C>A p.P972T | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA2 | c.4267G>T p.G1423W | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NELFB | c.1740+1G>T p.X580_splice | Splice Site (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- NLRC4 | c.1948T>A p.S650T | Missense Mutation (SNP) | VAF 59/296 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- NQO1 | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, varscan2
- NSG1 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 85/172 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NUDT12 | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 71/354 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NUDT7 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUP133 | c.1501-1G>T p.X501_splice | Splice Site (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- NUS1 | c.301A>T p.M101L | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); called by mutect2, varscan2
- NWD2 | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 214/481 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ODF2 | c.1093A>T p.M365L (on ENST00000434106 / NM_153433.2; = p.M341L on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/351 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGDHL | c.1133A>T p.E378V | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OLFM3 | c.1064G>T p.G355V (on ENST00000338858 / NM_001288821.1; = p.G335V on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10A2 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 60/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- OR10A3 | c.895A>T p.R299W | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR1S1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4D2 | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 242/689 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4K2 | c.453G>T p.M151I | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4P4 | c.89T>C p.L30S | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OR52N1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 109/356 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- OR5D16 | c.814A>T p.T272S | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OR6C75 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OSER1 | c.401G>T p.S134I | Missense Mutation (SNP) | VAF 65/456 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- OTUD7A | c.2467G>T p.A823S (on ENST00000307050 / NM_001382637.1; = p.A816S on NM_130901.3) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OVCH1 | c.2352G>T p.W784C | Missense Mutation (SNP) | VAF 64/699 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PALD1 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPOLB | c.1486del p.Q496Sfs*21 | Frame Shift Del (DEL) | VAF 50/420 reads (12%) | called by mutect2, pindel, varscan2
- PCDH11X | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 119/251 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PCDH7 | c.2015C>A p.A672E | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHB7 | c.1256T>A p.I419N | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHGA12 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PCDHGA2 | c.1900del p.D634Tfs*99 | Frame Shift Del (DEL) | VAF 64/359 reads (18%) | called by mutect2, pindel, varscan2
- PCDHGA4 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PEX1 | c.2677G>T p.V893L | Missense Mutation (SNP) | VAF 84/468 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PEX3 | c.329_331del p.I110del | In Frame Del (DEL) | VAF 46/284 reads (16%) | called by pindel, varscan2
- PGAP3 | c.695-1G>T p.X232_splice | Splice Site (SNP) | VAF 71/173 reads (41%) | called by muse, mutect2, varscan2
- PGBD2 | c.40A>T p.I14F | Missense Mutation (SNP) | VAF 80/291 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDB1 | c.3031A>T p.T1011S | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PI16 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- PKD1L1 | c.6065G>A p.G2022E | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PKD1L3 | c.3432del p.I1145Sfs*9 | Frame Shift Del (DEL) | VAF 92/343 reads (27%) | called by mutect2, pindel, varscan2
- PLB1 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLEKHG4B | c.3281C>A p.A1094E (on ENST00000283426; = p.A1450E on NM_052909.5) | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PLEKHG7 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PLPPR3 | c.1903C>A p.P635T (on ENST00000520876 / NM_001270366.2; = p.P663T on NM_024888.2) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PMFBP1 | c.2209G>T p.D737Y (on ENST00000537465; = p.D732Y on NM_031293.3) | Missense Mutation (SNP) | VAF 45/302 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PNLIPRP1 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PNMA8B | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R3C | c.810G>T p.M270I | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX1 | c.3602-1G>A p.X1201_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- PRMT9 | c.1708G>T p.G570* | Nonsense Mutation (SNP) | VAF 52/258 reads (20%) | called by muse, mutect2, varscan2
- PRRC2B | c.5636G>T p.G1879V | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PRRT1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); called by muse, varscan2
- PRRT4 | c.2392G>T p.G798C | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG9 | c.715C>A p.L239M | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, varscan2
- PSMD12 | c.950G>C p.W317S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PVRIG | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- RBFOX1 | c.601A>C p.T201P | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMS2 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- RGPD1 | c.2569G>T p.G857C (on ENST00000409776; = p.G865C on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RNF212 | c.879G>T p.R293S | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- RNF44 | c.465G>T p.P155= | Splice Region (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- SDC4 | c.198G>T p.L66= | Splice Region (SNP) | VAF 33/103 reads (32%) | called by muse, mutect2, varscan2
- SEC23A | c.1393A>T p.N465Y | Missense Mutation (SNP) | VAF 199/510 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, varscan2
- SEMA5A | c.1649C>A p.T550K | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SENP6 | c.2272G>T p.V758L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SH2D1B | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SH3TC2 | c.1936C>A p.L646I | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- SIGLEC12 | c.1784A>T p.K595M (on ENST00000291707 / NM_053003.4; = p.K477M on NM_033329.2) | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- SIGLEC8 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 217/725 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC24A1 | c.2702G>A p.W901* | Nonsense Mutation (SNP) | VAF 99/320 reads (31%) | called by muse, mutect2, varscan2
- SLC24A2 | c.1756C>A p.L586M | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SLC25A33 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.062); called by muse, mutect2
- SLC26A2 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A3 | c.1788G>T p.E596D (on ENST00000271857; = p.E468D on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- SLC28A1 | c.446T>C p.L149P | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SLC5A6 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SLIT1 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA4 | c.2890A>T p.I964F | Missense Mutation (SNP) | VAF 80/366 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SMCHD1 | c.2064-2A>C p.X688_splice | Splice Site (SNP) | VAF 46/142 reads (32%) | called by muse, varscan2
- SMIM21 | c.288C>A p.N96K | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SNCAIP | c.2441T>A p.L814Q | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNTG1 | c.220-2A>C p.X74_splice | Splice Site (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- SP9 | c.935A>C p.N312T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPAG5 | c.3198+4T>C | Splice Region (SNP) | VAF 83/232 reads (36%) | called by muse, mutect2, varscan2
- SPDYE2 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 82/890 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, varscan2
- SPEF2 | c.2839+2T>C p.X947_splice | Splice Site (SNP) | VAF 40/289 reads (14%) | called by muse, mutect2, varscan2
- SPEG | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SPNS1 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPPL2C | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SPTA1 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 58/496 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST14 | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 91/621 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ST6GAL2 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 18/191 reads (9%) | PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ST6GAL2 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 20/189 reads (11%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUPT5H | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SYCP2 | c.2717T>A p.V906E | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- SYNJ1 | c.1236-1G>T p.X412_splice | Splice Site (SNP) | VAF 66/242 reads (27%) | called by muse, mutect2, varscan2
- TACC2 | c.3825_3826del p.L1276Cfs*37 | Frame Shift Del (DEL) | VAF 39/258 reads (15%) | called by mutect2, pindel, varscan2
- TAF5L | c.1066G>T p.G356W | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TDRD15 | c.2836C>A p.P946T | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TECRL | c.466C>A p.L156I | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TENM4 | c.2474G>T p.W825L | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TENT5D | c.580C>A p.L194I | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TESPA1 | c.1332G>T p.Q444H (on ENST00000316577 / NM_001098815.3; = p.Q306H on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/343 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TFR2 | c.1380G>C p.M460I | Missense Mutation (SNP) | VAF 112/647 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- THBS1 | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TIAM1 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TM2D2 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- TMEM132C | c.1542C>A p.S514R | Missense Mutation (SNP) | VAF 142/526 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TMEM132C | c.3005C>A p.P1002Q | Missense Mutation (SNP) | VAF 81/257 reads (32%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- TMEM132E | c.2876C>A p.P959Q (on ENST00000321639; = p.P1049Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMOD1 | c.167A>G p.K56R | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNRC18 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TP53BP2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 128/425 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TPO | c.282G>C p.M94I | Missense Mutation (SNP) | VAF 50/391 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TPTE | c.1231dup p.R411Kfs*20 (on ENST00000618007 / NM_199261.4; = p.R393Kfs*20 on NM_199259.4) | Frame Shift Ins (INS) | VAF 56/486 reads (12%) | called by mutect2, pindel, varscan2
- TRANK1 | c.4927C>A p.L1643M | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPYL2 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TTI1 | c.741G>T p.M247I | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TTK | c.2208G>T p.Q736H | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE4A | c.408+1G>T p.X136_splice | Splice Site (SNP) | VAF 74/207 reads (36%) | called by muse, mutect2, varscan2
- ULK2 | c.835+1G>A p.X279_splice | Splice Site (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- VGLL2 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VN1R5 | c.844T>A p.W282R | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WHRN | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- WWC1 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZBED9 | c.267G>T p.E89D | Missense Mutation (SNP) | VAF 55/423 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZCCHC8 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 100/350 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZDBF2 | c.5592G>C p.E1864D | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ZNF235 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF25 | c.15+1G>T p.X5_splice | Splice Site (SNP) | VAF 52/279 reads (19%) | called by muse, mutect2, varscan2
- ZNF281 | c.2608G>T p.G870W | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF407 | c.3689G>T p.C1230F | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZNF469 | c.2314G>T p.G772W | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF486 | c.1170del p.A391Qfs*31 | Frame Shift Del (DEL) | VAF 104/249 reads (42%) | called by mutect2, pindel*, varscan2
- ZNF487 | c.177A>T p.Q59H | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ZNF490 | c.583A>T p.K195* | Nonsense Mutation (SNP) | VAF 87/239 reads (36%) | called by muse, mutect2, varscan2
- ZNF492 | c.512G>T p.C171F | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZNF536 | c.3419A>T p.H1140L | Missense Mutation (SNP) | VAF 100/390 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); called by muse, varscan2
- ZNF609 | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM12 | c.1771C>A p.R591= | Silent (SNP) | VAF 106/381 reads (28%) | catalogued as COSV64114150; called by muse, mutect2, varscan2
- ADAM7 | c.780A>G p.L260= | Silent (SNP) | VAF 46/245 reads (19%) | called by muse, mutect2, varscan2
- ADD2 | c.711G>T p.S237= | Silent (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- AMER3 | c.1816C>A p.R606= | Silent (SNP) | VAF 68/187 reads (36%) | catalogued as COSV100365992; called by muse, mutect2, varscan2
- BPIFC | c.819C>T p.R273= | Silent (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- CACNA1B | c.5811C>T p.V1937= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.3087A>T p.R1029= (on ENST00000356253 / NM_001366867.1; = p.R1017= on NM_000722.4) | Silent (SNP) | VAF 58/375 reads (15%) | catalogued as COSV100666084; called by muse, mutect2, varscan2
- COL2A1 | c.3316C>A p.R1106= | Silent (SNP) | VAF 172/497 reads (35%) | called by muse, mutect2, varscan2
- COL4A1 | c.849A>T p.P283= | Silent (SNP) | VAF 193/393 reads (49%) | called by muse, mutect2, varscan2
- CSMD1 | c.9039A>G p.S3013= (on ENST00000520002; = p.S3012= on NM_033225.6) | Silent (SNP) | VAF 35/294 reads (12%) | catalogued as rs1326037234, COSV59290333; called by muse, mutect2, varscan2
- DNAJB8 | c.558C>T p.T186= | Silent (SNP) | VAF 93/223 reads (42%) | catalogued as rs563290082; called by muse, mutect2, varscan2
- DPY19L4 | c.1158T>C p.F386= | Silent (SNP) | VAF 78/269 reads (29%) | called by muse, mutect2, varscan2
- DSP | c.8538G>C p.R2846= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as COSV100673080; called by muse, mutect2, varscan2
- EARS2 | c.438G>T p.R146= | Silent (SNP) | VAF 47/197 reads (24%) | called by muse, mutect2, varscan2
- ECH1 | c.438C>T p.I146= | Silent (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
- EPS8 | c.159G>T p.R53= | Silent (SNP) | VAF 91/465 reads (20%) | called by muse, mutect2, varscan2
- FAM78B | c.510G>T p.T170= | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- FAT3 | c.11130C>T p.S3710= | Silent (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
- FBXL7 | c.1167C>A p.I389= | Silent (SNP) | VAF 17/205 reads (8%) | called by muse, mutect2
- FCRL5 | c.1725C>A p.A575= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV62514805; called by muse, mutect2, varscan2
- FLG | c.4134T>A p.A1378= | Silent (SNP) | VAF 92/713 reads (13%) | catalogued as COSV64238086; called by muse, mutect2
- GABRG3 | c.903C>T p.T301= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs1470515891; called by muse, mutect2, varscan2
- GBA | c.1413G>A p.Q471= | Silent (SNP) | VAF 114/563 reads (20%) | catalogued as rs12747811; called by muse, mutect2, varscan2
- GJA9 | c.666A>T p.S222= | Silent (SNP) | VAF 118/225 reads (52%) | catalogued as COSV62531969; called by muse, mutect2, varscan2
- GPR179 | c.6498G>A p.T2166= (on ENST00000621958; = p.T2165= on NM_001004334.4) | Silent (SNP) | VAF 80/496 reads (16%) | catalogued as rs201374947; called by muse, mutect2, varscan2
- GRIA2 | c.258T>C p.Y86= | Silent (SNP) | VAF 52/207 reads (25%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.168C>A p.A56= | Silent (SNP) | VAF 172/1042 reads (17%) | called by muse, varscan2
- IL17RD | c.1026A>G p.T342= | Silent (SNP) | VAF 58/162 reads (36%) | called by muse, mutect2, varscan2
- IL36G | c.291G>A p.L97= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- INAVA | c.1734G>T p.R578= | Silent (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
- INSR | c.1134A>T p.A378= | Silent (SNP) | VAF 182/410 reads (44%) | called by mutect2, varscan2
- ITPR1 | c.792G>T p.L264= | Silent (SNP) | VAF 66/166 reads (40%) | called by muse, varscan2
- JPH3 | c.666G>A p.G222= | Silent (SNP) | VAF 176/443 reads (40%) | catalogued as rs1405825456; called by muse, mutect2, varscan2
- KCNA5 | c.591G>T p.A197= | Silent (SNP) | VAF 136/746 reads (18%) | called by muse, mutect2, varscan2
- KCNG1 | c.124C>A p.R42= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs536118359, COSV65369663, COSV65370694; called by muse, mutect2, varscan2
- KCNQ4 | c.183G>A p.P61= | Silent (SNP) | VAF 98/204 reads (48%) | called by muse, mutect2, varscan2
- KIF2B | c.1929C>G p.S643= | Silent (SNP) | VAF 40/259 reads (15%) | called by muse, mutect2, varscan2
- KMT2B | c.6477C>T p.P2159= | Silent (SNP) | VAF 59/177 reads (33%) | catalogued as rs755391068; called by muse, mutect2, varscan2
- LAMA5 | c.2184C>T p.A728= | Silent (SNP) | VAF 80/421 reads (19%) | catalogued as rs140214749; called by muse, mutect2, varscan2
- LAMC3 | c.150C>T p.A50= | Silent (SNP) | VAF 52/208 reads (25%) | called by muse, mutect2, varscan2
- LARP6 | c.789C>T p.F263= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs371562863; called by muse, mutect2, varscan2
- LILRA1 | c.1179G>C p.G393= | Silent (SNP) | VAF 216/684 reads (32%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.663C>A p.S221= | Silent (SNP) | VAF 82/234 reads (35%) | called by muse, mutect2, varscan2
- LINGO1 | c.129G>T p.P43= | Silent (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- LMTK2 | c.4353G>T p.P1451= | Silent (SNP) | VAF 189/574 reads (33%) | catalogued as COSV51998889; called by muse, mutect2, varscan2
- LRP1B | c.10110T>A p.A3370= | Silent (SNP) | VAF 36/295 reads (12%) | called by muse, mutect2, varscan2
- LSS | c.1203G>T p.G401= | Silent (SNP) | VAF 46/160 reads (29%) | called by muse, mutect2, varscan2
- MAGEB5 | c.693C>A p.A231= | Silent (SNP) | VAF 64/144 reads (44%) | called by muse, mutect2, varscan2
- MED14 | c.4197A>T p.A1399= | Silent (SNP) | VAF 88/185 reads (48%) | called by muse, mutect2, varscan2
- MPV17 | c.33G>T p.L11= | Silent (SNP) | VAF 167/469 reads (36%) | called by muse, mutect2, varscan2
- MRM1 | c.681C>T p.C227= | Silent (SNP) | VAF 73/239 reads (31%) | called by muse, mutect2, varscan2
- MROH2A | c.1836C>T p.P612= | Silent (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- MRPL39 | c.789G>T p.V263= | Silent (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- MUC12 | c.1566T>G p.T522= (on ENST00000379442; = p.T379= on NM_001164462.1) | Silent (SNP) | VAF 62/804 reads (8%) | called by muse, mutect2
- MUC7 | c.843A>T p.T281= | Silent (SNP) | VAF 110/519 reads (21%) | called by muse, mutect2, varscan2
- MYBL2 | c.798A>G p.T266= | Silent (SNP) | VAF 148/472 reads (31%) | called by muse, mutect2, varscan2
- NCKAP5L | c.2064C>T p.A688= | Silent (SNP) | VAF 43/208 reads (21%) | called by muse, mutect2, varscan2
- NINL | c.3153G>A p.L1051= | Silent (SNP) | VAF 50/338 reads (15%) | called by muse, mutect2, varscan2
- NMUR1 | c.492G>T p.V164= | Silent (SNP) | VAF 74/183 reads (40%) | called by muse, mutect2, varscan2
- NOTCH1 | c.4866C>T p.R1622= | Silent (SNP) | VAF 52/280 reads (19%) | catalogued as rs772314400, COSV53073155; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10A2 | c.522G>T p.L174= | Silent (SNP) | VAF 59/318 reads (19%) | called by muse, mutect2, varscan2
- OR11L1 | c.342C>A p.L114= | Silent (SNP) | VAF 55/328 reads (17%) | called by muse, mutect2
- OR1L4 | c.372G>C p.L124= | Silent (SNP) | VAF 65/262 reads (25%) | called by muse, varscan2
- OR4Q3 | c.402C>A p.A134= | Silent (SNP) | VAF 75/290 reads (26%) | catalogued as COSV59179360, COSV59179870; called by muse, mutect2, varscan2
- OR52N4 | c.339G>A p.E113= | Silent (SNP) | VAF 28/258 reads (11%) | catalogued as rs1430698720; called by muse, mutect2, varscan2
- OR5B17 | c.132C>A p.I44= | Silent (SNP) | VAF 39/254 reads (15%) | called by muse, mutect2, varscan2
- OR6N2 | c.783G>T p.R261= | Silent (SNP) | VAF 12/244 reads (5%) | called by muse, mutect2
- PARP16 | c.366G>T p.P122= | Silent (SNP) | VAF 69/410 reads (17%) | catalogued as rs200911696, COSV99975229; called by muse, mutect2, varscan2
- PCDH7 | c.2016A>G p.A672= | Silent (SNP) | VAF 38/320 reads (12%) | called by muse, mutect2, varscan2
- PCLO | c.7824A>T p.S2608= | Silent (SNP) | VAF 59/211 reads (28%) | catalogued as COSV61671626; called by muse, mutect2, varscan2
- PER3 | c.240C>T p.L80= | Silent (SNP) | VAF 43/166 reads (26%) | called by muse, mutect2, varscan2
- PKD1L2 | c.54C>A p.T18= | Silent (SNP) | VAF 80/180 reads (44%) | called by muse, mutect2, varscan2
- PKLR | c.1110C>A p.A370= | Silent (SNP) | VAF 26/682 reads (4%) | called by muse, mutect2
- PPEF2 | c.1206G>A p.R402= | Silent (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- PRSS54 | c.561C>A p.I187= | Silent (SNP) | VAF 87/276 reads (32%) | catalogued as rs142166944, COSV54685011; called by muse, mutect2, varscan2
- PSG7 | c.943C>A p.R315= | Silent (SNP) | VAF 100/294 reads (34%) | catalogued as rs751567313; called by muse, mutect2, varscan2
- PTCHD3 | c.1566C>A p.T522= | Silent (SNP) | VAF 76/198 reads (38%) | called by muse, varscan2
- PZP | c.2970C>A p.I990= | Silent (SNP) | VAF 211/393 reads (54%) | called by muse, mutect2, varscan2
- REN | c.165G>A p.R55= | Silent (SNP) | VAF 85/525 reads (16%) | called by muse, mutect2, varscan2
- RHOT2 | c.1347G>A p.Q449= | Silent (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- RIT1 | c.537A>T p.V179= | Silent (SNP) | VAF 90/536 reads (17%) | called by muse, mutect2, varscan2
- ROCK1 | c.540A>T p.A180= | Silent (SNP) | VAF 49/181 reads (27%) | called by muse, mutect2, varscan2
- SDAD1 | c.84C>T p.I28= | Silent (SNP) | VAF 82/380 reads (22%) | called by muse, mutect2, varscan2
- SDK2 | c.4182C>T p.T1394= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs548698767; called by muse, mutect2, varscan2
- SETD5 | c.366G>T p.R122= | Silent (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- SH2D5 | c.660C>A p.A220= (on ENST00000444387 / NM_001103161.2; = p.A136= on NM_001103160.2) | Silent (SNP) | VAF 73/159 reads (46%) | called by mutect2, varscan2
- SIGLECL1 | c.192C>A p.P64= | Silent (SNP) | VAF 51/254 reads (20%) | called by muse, mutect2, varscan2
- SLC1A7 | c.234C>T p.A78= | Silent (SNP) | VAF 103/235 reads (44%) | called by muse, mutect2, varscan2
- SLC30A10 | c.747C>A p.A249= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- SLC41A1 | c.1299G>T p.G433= | Silent (SNP) | VAF 91/442 reads (21%) | called by muse, mutect2, varscan2
- SPAM1 | c.66G>A p.Q22= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV56142862; called by muse, mutect2, varscan2
- SPDYE6 | c.1074G>T p.L358= | Silent (SNP) | VAF 77/651 reads (12%) | called by muse, mutect2, varscan2
- STAB1 | c.3039C>A p.I1013= | Silent (SNP) | VAF 64/125 reads (51%) | called by muse, mutect2, varscan2
- STK32A | c.339A>G p.Q113= | Silent (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- STOML1 | c.642C>T p.R214= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs757714373, COSV100381858; called by muse, mutect2, varscan2
- SYNE1 | c.753G>T p.G251= (on ENST00000367255 / NM_182961.4; = p.G258= on NM_033071.3) | Silent (SNP) | VAF 52/370 reads (14%) | called by muse, mutect2, varscan2
- TAL1 | c.195C>G p.A65= | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs920634129; called by muse, mutect2, varscan2
- TMC2 | c.1797G>C p.L599= | Silent (SNP) | VAF 36/211 reads (17%) | catalogued as COSV62657249; called by muse, mutect2, varscan2
- TPST2 | c.18G>T p.R6= | Silent (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- TRPC6 | c.210A>C p.T70= | Silent (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- UBAP2 | c.2157C>T p.S719= | Silent (SNP) | VAF 48/290 reads (17%) | catalogued as rs1234974691; called by muse, mutect2, varscan2
- UBE3A | c.1740G>A p.E580= | Silent (SNP) | VAF 104/398 reads (26%) | called by muse, mutect2, varscan2
- UBQLNL | c.1044C>T p.T348= | Silent (SNP) | VAF 83/261 reads (32%) | called by muse, mutect2, varscan2
- UMOD | c.1650C>A p.V550= | Silent (SNP) | VAF 68/329 reads (21%) | catalogued as rs755997328; called by muse, mutect2, varscan2
- USH2A | c.11757A>T p.S3919= | Silent (SNP) | VAF 56/257 reads (22%) | catalogued as rs775892043; called by muse, mutect2, varscan2
- VIT | c.588C>T p.T196= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV64896774; called by muse, mutect2, varscan2
- WDFY4 | c.5109C>A p.V1703= | Silent (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
- XIRP2 | c.2775C>A p.T925= (on ENST00000628543; = p.T1100= on NM_152381.6) | Silent (SNP) | VAF 75/233 reads (32%) | catalogued as COSV99739026; called by muse, mutect2, varscan2
- YAF2 | c.384A>C p.T128= | Silent (SNP) | VAF 156/492 reads (32%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.738G>T p.R246= | Silent (SNP) | VAF 93/299 reads (31%) | called by muse, mutect2, varscan2
- ZEB1 | c.3183G>T p.G1061= | Silent (SNP) | VAF 152/417 reads (36%) | called by muse, varscan2
- ZFP57 | c.1200C>A p.S400= | Silent (SNP) | VAF 252/906 reads (28%) | called by muse, mutect2, varscan2
- ZNF585B | c.252A>G p.P84= | Silent (SNP) | VAF 46/452 reads (10%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5012G>T | RNA (SNP) | VAF 50/532 reads (9%) | called by muse, mutect2
- AC024940.1 | n.3343del | RNA (DEL) | VAF 118/166 reads (71%) | called by mutect2, varscan2
- AC104078.1 | n.244C>A | RNA (SNP) | VAF 46/319 reads (14%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-7757G>T | Intron (SNP) | VAF 90/259 reads (35%) | catalogued as rs143195891; called by muse, mutect2, varscan2
- ACACA | c.5349+13A>G | Intron (SNP) | VAF 71/222 reads (32%) | catalogued as rs765456395; called by muse, mutect2, varscan2
- ADAM23 | c.*80T>C | 3'UTR (SNP) | VAF 71/155 reads (46%) | catalogued as rs1260276079; called by muse, mutect2, varscan2
- AVPR2 | c.*142T>A | 3'UTR (SNP) | VAF 35/57 reads (61%) | called by muse, mutect2, varscan2
- BAGE2 | n.43T>A | RNA (SNP) | VAF 72/580 reads (12%) | called by muse, mutect2, varscan2
- BMERB1 | chr16:15591092 G>T | 3'Flank (SNP) | VAF 37/300 reads (12%) | called by muse, mutect2, varscan2
- C1orf229 | n.385C>A | RNA (SNP) | VAF 35/88 reads (40%) | called by muse, mutect2, varscan2
- C1orf56 | c.*22_*24del | 3'UTR (DEL) | VAF 44/134 reads (33%) | catalogued as rs773127084; called by pindel, varscan2
- C4A | chr6:32006172 G>A | 3'Flank (SNP) | VAF 15/144 reads (10%) | catalogued as rs777804004; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-121-25682C>T | Intron (SNP) | VAF 30/288 reads (10%) | catalogued as COSV66968996; called by muse, mutect2
- CAPRIN1 | c.1-68G>T | Intron (SNP) | VAF 58/182 reads (32%) | called by muse, mutect2, varscan2
- CDK11A | chr1:1701158 C>A | 3'Flank (SNP) | VAF 99/758 reads (13%) | called by muse, varscan2
- CELF2 | c.1076-2082A>T | Intron (SNP) | VAF 55/172 reads (32%) | called by muse, mutect2, varscan2
- CGB7 | c.-19G>T | 5'UTR (SNP) | VAF 31/155 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.6246G>T | RNA (SNP) | VAF 55/256 reads (21%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.86+127G>T | Intron (SNP) | VAF 20/187 reads (11%) | called by muse, mutect2, varscan2
- DUOX2 | c.1399-34A>G | Intron (SNP) | VAF 43/128 reads (34%) | called by muse, mutect2, varscan2
- EFL1P1 | n.1693C>A | RNA (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2, varscan2
- EPB41L1 | c.1669-2555G>T | Intron (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- EPC2 | c.313+1241C>G | Intron (SNP) | VAF 60/318 reads (19%) | called by muse, mutect2, varscan2
- EPS8L2 | c.895+92G>T | Intron (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- FAM90A27P | n.516G>T | RNA (SNP) | VAF 44/228 reads (19%) | called by muse, mutect2
- G2E3 | c.1501-25G>T | Intron (SNP) | VAF 33/183 reads (18%) | called by muse, varscan2
- GFPT2 | c.7+442G>T | Intron (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- GNL2 | c.909+707G>T | Intron (SNP) | VAF 138/268 reads (51%) | called by muse, mutect2, varscan2
- GRHPR | c.865+30C>T | Intron (SNP) | VAF 77/480 reads (16%) | catalogued as rs1307498666; called by muse, mutect2, varscan2
- GRHPR | c.865+31C>A | Intron (SNP) | VAF 74/468 reads (16%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.1626G>T | RNA (SNP) | VAF 167/580 reads (29%) | called by muse, varscan2
- GVINP1 | n.4053C>A | RNA (SNP) | VAF 117/358 reads (33%) | called by muse, mutect2, varscan2
- GYPA | c.37+2370C>A | Intron (SNP) | VAF 25/228 reads (11%) | called by muse, mutect2, varscan2
- HAGHL | c.*247G>C | 3'UTR (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- HPN-AS1 | n.167C>G | RNA (SNP) | VAF 53/268 reads (20%) | called by muse, mutect2, varscan2
- HTR7 | c.-6G>T | 5'UTR (SNP) | VAF 60/180 reads (33%) | catalogued as COSV53287893; called by muse, mutect2, varscan2
- IFT43 | c.248+83C>T | Intron (SNP) | VAF 91/197 reads (46%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.120C>A | RNA (SNP) | VAF 66/314 reads (21%) | catalogued as rs543019617; called by muse, varscan2
- LHB | c.*59C>A | 3'UTR (SNP) | VAF 118/416 reads (28%) | called by muse, mutect2, varscan2
- LINC00602 | n.1282G>C | RNA (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- LINC01193 | n.872C>A | RNA (SNP) | VAF 35/590 reads (6%) | called by muse, mutect2
- LINGO1 | chr15:77634281 G>T | 5'Flank (SNP) | VAF 87/277 reads (31%) | called by muse, mutect2, varscan2
- LLCFC1 | c.157+76G>T | Intron (SNP) | VAF 16/68 reads (24%) | called by muse, varscan2
- MARK3 | c.483+1552C>T | Intron (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- MCAM | c.560-123C>A | Intron (SNP) | VAF 44/321 reads (14%) | called by muse, mutect2, varscan2
- MEFV | c.*948A>T | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- MICU3 | c.694+133A>G | Intron (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2, varscan2
- MIR1185-2 | n.49G>A | RNA (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- MIR302E | chr11:7238870 G>T | 3'Flank (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- MIR6511A2 | chr16:16325125 del G | 3'Flank (DEL) | VAF 83/695 reads (12%) | called by pindel, varscan2
- MIR6511A3 | chr16:16371527 C>A | 3'Flank (SNP) | VAF 192/1109 reads (17%) | called by muse, mutect2, varscan2
- MOB4 | c.60+45_60+50del | Intron (DEL) | VAF 17/130 reads (13%) | called by mutect2, pindel*, varscan2
- MXD4 | c.165-982G>T | Intron (SNP) | VAF 78/161 reads (48%) | catalogued as rs373133963; called by muse, mutect2, varscan2
- MYH11 | c.2521-21G>A | Intron (SNP) | VAF 150/588 reads (26%) | called by muse, mutect2, varscan2
- MYH14 | c.*77A>G | 3'UTR (SNP) | VAF 67/245 reads (27%) | called by muse, mutect2, varscan2
- NT5DC3 | c.-39_-30del | 5'UTR (DEL) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- OAS1 | c.*79A>T | 3'UTR (SNP) | VAF 68/222 reads (31%) | called by muse, mutect2, varscan2
- OR2U1P | n.813G>T | RNA (SNP) | VAF 81/193 reads (42%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157758 G>A | 3'Flank (SNP) | VAF 103/512 reads (20%) | catalogued as rs782472138; called by muse, mutect2, varscan2
- PLCB1 | c.2524-6157C>A | Intron (SNP) | VAF 27/194 reads (14%) | catalogued as COSV62044796; called by muse, mutect2, varscan2
- PTGDS | c.551-56G>A | Intron (SNP) | VAF 42/212 reads (20%) | catalogued as COSV56401144; called by muse, mutect2, varscan2
- RASGRP2 | c.-71-128del | Intron (DEL) | VAF 34/185 reads (18%) | called by mutect2, pindel, varscan2
- RGMA | c.130+6702A>G | Intron (SNP) | VAF 99/301 reads (33%) | called by muse, mutect2, varscan2
- RNFT2 | c.*3273A>G | 3'UTR (SNP) | VAF 113/319 reads (35%) | called by muse, mutect2, varscan2
- RNU1-20P | chr3:192727197 G>T | 3'Flank (SNP) | VAF 117/301 reads (39%) | called by muse, mutect2, varscan2
- RPGR | c.2520+1543G>T | Intron (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- SMTN | c.1632+1617G>T | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- SRGAP2 | c.2358-724T>A | Intron (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- TBC1D15 | c.30+15026C>T | Intron (SNP) | VAF 83/287 reads (29%) | called by muse, mutect2, varscan2
- TMED9 | c.185-45C>A | Intron (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- TMEM214 | c.1153-82G>T | Intron (SNP) | VAF 71/212 reads (33%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.5544+257G>T | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23189G>A | Intron (SNP) | VAF 115/305 reads (38%) | called by muse, mutect2, varscan2
- VGF | c.*195C>A | 3'UTR (SNP) | VAF 68/203 reads (33%) | called by muse, mutect2, varscan2
- VGLL3 | c.937+5640G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- WASF4P | n.932G>T | RNA (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- WIPF1 | c.358+264G>T | Intron (SNP) | VAF 56/188 reads (30%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.772-1338G>T | Intron (SNP) | VAF 60/201 reads (30%) | called by muse, mutect2, varscan2
- ZNF670-ZNF695 | c.*231T>A | 3'UTR (SNP) | VAF 51/318 reads (16%) | called by muse, mutect2, varscan2
- ZNF670-ZNF695 | c.*230C>A | 3'UTR (SNP) | VAF 51/317 reads (16%) | called by muse, mutect2, varscan2
- ZNF720 | c.361+82C>A | Intron (SNP) | VAF 71/255 reads (28%) | called by muse, mutect2, varscan2
